Gene-level copy-number profile of tumor specimen TCGA-39-5037-01A from TCGA case TCGA-39-5037, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.3 years (23,868 days).
Specimen TCGA-39-5037-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a5fe1f34-09b2-49da-a222-6eb8d3a08818.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-39-5037-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/952fa3dc-7135-4573-9302-ee0e1a7b00ea

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 2: 1,188; copy number 3: 4,379; copy number 4: 20,145; copy number 5: 8,596; copy number 6: 10,414; copy number 7: 5,568; copy number 8: 4,305; copy number 9: 2,615; copy number 10: 985; copy number 11: 383; copy number 12: 34; copy number 13: 11; copy number 14: 248; copy number 15: 111; copy number 16: 129; copy number 17: 187; copy number 18: 55; copy number 20: 213; copy number 22: 107; copy number 23: 9; copy number 26: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-39-5037-01A-01D-1439-01): tumor purity 0.49, ploidy 4.22, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,058,771–26,644,595, 80 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5,133 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–153,113,516, 408 genes, copy number 9 (broad region; genes not listed).
- chr1:154,924,740–188,144,768, 844 genes, copy number 9–11 (broad region; genes not listed).
- chr2:48,809,340–68,467,294, 293 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr2:96,184,859–113,704,078, 405 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr3:138,947,217–198,222,513, 1,035 genes, copy number 14–26 (within-gene range 4–26) (broad region; genes not listed).
- chr5:28,808,538–29,600,868, 14 genes, copy number 10–13: AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1.
- chr6:50,587,607–53,418,737, 65 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr6:53,503,109–53,507,660, 1 gene, copy number 9: AL033397.2.
- chr6:56,276,529–58,438,364, 32 genes, copy number 9 (within-gene range 6–9): DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr6:72,621,792–73,198,853, 6 genes, copy number 11 (within-gene range 6–11): KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1.
- chr7:25,118,656–57,837,046, 680 genes, copy number 10 (broad region; genes not listed).
- chr8:37,421,341–39,730,065, 69 genes, copy number 10–12 (within-gene range 5–12) (broad region; genes not listed).
- chr9:26,746,953–27,844,481, 24 genes, copy number 12–20: AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1.
- chr11:69,294,151–69,367,726, 1 gene, copy number 20 (within-gene range 7–20): MYEOV.
- chr11:69,371,463–71,629,421, 62 genes, copy number 20 (broad region; genes not listed).
- chr11:81,970,994–81,987,813, 1 gene, copy number 11: AP002802.1.
- chr11:90,869,121–91,383,289, 10 genes, copy number 9: MIR1261, AP001002.3, AP001002.1, AP001002.2, OSBPL9P2, OSBPL9P3, LINC02748, AP003485.2, AP003485.1, AP002791.1.
- chr12:14,169,746–29,784,759, 250 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr20:87,250–31,259,632, 573 genes, copy number 9 (broad region; genes not listed).
- chr22:15,290,718–18,024,561, 105 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr22:33,014,980–38,794,198, 181 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr22:45,875,932–49,838,901, 74 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
